Gene-level copy-number profile of tumor specimen TCGA-KK-A7AQ-01A from TCGA case TCGA-KK-A7AQ, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 62.2 years (22,731 days).
Specimen TCGA-KK-A7AQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.d311c39f-1f08-47aa-8d6b-63b99167c953.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KK-A7AQ-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bfbecd1a-9b5b-4db9-b901-d5b9807acdcc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 173; copy number 1: 6,878; copy number 2: 52,215; copy number 3: 552.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KK-A7AQ-01A-11D-A33S-01): tumor purity 0.76, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 149 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:121,902,501–123,073,481, 4 genes (within-gene range 0–1): AC011246.1, AC073632.1, AC062020.1, LINC01826.
- chr2:124,932,915–125,823,315, 5 genes: RNA5SP102, RNU6-259P, AC097499.2, LINC01889, AC097499.1.
- chr2:138,669,157–143,768,352, 43 genes (within-gene range 0–1): NXPH2, RN7SKP286, YY1P2, AHCYP4, AC023468.1, AC013265.1, AC062021.1, AC016710.1, SNORA72, MRPS18BP2, RPL9P13, AC078851.1, RN7SL283P, LINC01853, MTCO1P44, MTND2P19, MTND1P27, LRP1B, AC092156.1, MIR7157, COPRSP1, LRRC57P1, Y_RNA, RNU6-904P, RPS16P3, AC078882.1, UBE2V1P14, RRN3P4, KYNU, SFXN4P1, ARHGAP15, MTCYBP11, MTND6P11, MTND5P24, MTND4P22, MTND4LP12, MTND3P9, MTCO3P5, MTATP6P5, MTCO2P5, AC013437.1, AC079793.1, AC092652.2.
- chr4:64,275,257–64,433,215, 3 genes: TECRL, RNU6-191P, DPP3P1.
- chr4:169,791,221–169,867,346, 3 genes: PTGES3P3, AC079768.1, AC079768.3.
- chr4:170,481,695–173,041,559, 16 genes (within-gene range 0–1): AC074255.1, HSP90AA6P, LINC02382, AC097486.1, RNU6ATAC13P, AC034159.2, LINC02431, AC034159.1, AC092639.1, MIR6082, LINC02504, AC074254.2, LINC02174, AC074254.1, GALNTL6, AC108064.1.
- chr5:97,799,404–98,995,013, 22 genes (within-gene range 0–1): AC122697.1, LINC02234, AC008834.1, LINC01846, AC116347.1, PSME2P1, AC233964.1, KRT8P32, MRPS35P2, MTCO2P24, MTCO1P24, CTBP2P4, DDX18P4, RGMB, RGMB-AS1, AC008522.1, CSNK1A1P3, CHD1, RNU6-402P, LINC02062, Y_RNA, AC022121.1.
- chr5:106,815,197–107,195,332, 2 genes: LINC01950, PSMC1P5.
- chr6:113,791,829–116,254,075, 26 genes (within-gene range 0–1): FO393415.2, FO393415.1, MARCKS, MROCKI, LINC02880, HDAC2, HDAC2-AS2, NUDT19P3, HS3ST5, RPSAP43, RNA5SP213, DNAJA1P4, AL138830.2, AL138830.1, AL590550.1, RNU6-475P, AL606845.1, LINC02534, FRK, AL357141.1, TPI1P3, NT5DC1, COL10A1, NIP7P3, AL050331.2, TSPYL4.
- chr6:116,258,493–116,279,930, 2 genes: AL050331.1, TSPYL1.
- chr10:84,138,420–85,537,483, 22 genes: AL603756.1, GHITM, CERNA2, C10orf99, CDHR1, LRIT2, RGR, LRIT1, LINC00858, CCSER2, RPL12P29, TNPO1P1, CACYBPP1, RPS3AP5, AL358787.2, LINC01519, AL358787.1, LINC02647, AC025428.1, LINC01520, AL731532.1, RNU6-325P.
- chr10:88,048,135–88,049,823, 1 gene: MED6P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4,515. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
